Somatic mutation profile of tumor specimen TCGA-X6-A7WB-01A (aliquot TCGA-X6-A7WB-01A-11D-A351-09) from TCGA case TCGA-X6-A7WB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 58.8 years (21,467 days).
Specimen TCGA-X6-A7WB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7f66a63-7cb0-432e-9716-90155301bcbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A7WB-10A (Blood Derived Normal), aliquot TCGA-X6-A7WB-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d30c69bd-37fb-404c-a7ee-b98bed72339a

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Nonsense Mutation 5, Splice Region 1, RNA 1, 5'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 21/24 reads (88%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ADA | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100866549; called by muse, mutect2
- ADAM30 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV101023751; called by muse, varscan2
- ANKRD6 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100329364; called by muse, mutect2, varscan2
- ARHGEF10 | c.3714G>T p.E1238D (on ENST00000398564; = p.E1213D on NM_014629.4) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100033657; called by muse, mutect2
- ARID4A | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100793974; called by muse, mutect2
- ATP1A3 | c.1567A>G p.T523A (on ENST00000545399 / NM_001256214.2; = p.T510A on NM_152296.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100131910; called by muse, mutect2, varscan2
- ATP6V1B2 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV99369202; called by muse, mutect2
- ATR | c.4961C>A p.A1654D | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100637641; called by muse, mutect2
- BCORL1 | c.4010G>T p.S1337I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs866613249, COSV99498344; called by mutect2, varscan2
- BRSK2 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100372278; called by muse, mutect2, varscan2
- C1orf216 | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99230222; called by muse, mutect2, varscan2
- CD1E | c.309T>A p.S103R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100936894; called by muse, mutect2, varscan2
- CDH22 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.643); catalogued as COSV100952691; called by muse, mutect2
- CENPE | c.3068C>A p.A1023D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV99476864; called by muse, mutect2
- CEP85L | c.1722G>C p.K574N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV100874027, COSV100874314; called by muse, mutect2, varscan2
- CLCNKA | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100509839; called by muse, mutect2, varscan2
- CPLX3 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100547532; called by muse, mutect2, varscan2
- CRYL1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100004079; called by muse, mutect2, varscan2
- CSRP3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs45531937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.733); catalogued as COSV99607230; called by muse, mutect2, varscan2
- DNAH3 | c.5005G>A p.V1669I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV99764723; called by muse, mutect2, varscan2
- EHMT2 | c.708G>C p.L236= | Splice Region (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100977109; called by muse, mutect2, varscan2
- FBXO6 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335748; called by mutect2, varscan2
- FRY | c.7469G>T p.S2490I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100968774; called by muse, mutect2, varscan2
- GABBR1 | c.2103G>A p.W701* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100589405; called by muse, mutect2, varscan2
- GRIN2D | c.2153C>A p.T718K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54379328; called by muse, mutect2, varscan2
- GRIN3A | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100701352; called by muse, mutect2, varscan2
- HNRNPUL2 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53665099; called by muse, mutect2, varscan2
- HPR | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99930753; called by mutect2, varscan2
- LAMB4 | c.2020A>G p.T674A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); catalogued as COSV99222562; called by muse, mutect2, varscan2
- LCE1B | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs145979350; called by muse, mutect2, varscan2
- MGAT5B | c.1462T>C p.Y488H (on ENST00000569840 / NM_001199172.2; = p.Y486H on NM_144677.3) | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100047181; called by muse, mutect2, varscan2
- MRM2 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642553; called by mutect2, varscan2
- MRPS34 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99167641; called by mutect2, varscan2
- MTREX | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs1256319903, COSV100043475; called by muse, mutect2
- MUC17 | c.12261G>T p.E4087D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100071424; called by muse, mutect2, varscan2
- MYH7 | c.4687C>A p.L1563M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV100805659; called by mutect2, varscan2
- NAGS | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243684; called by mutect2, varscan2
- NTSR1 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV100980608; called by mutect2, varscan2
- OR10Z1 | c.737C>A p.T246K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV100778929, COSV63523961; called by muse, mutect2, varscan2
- OR5A1 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV100118199, COSV100118430, COSV57378840; called by muse, mutect2, varscan2
- OR7D2 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs375997272; called by muse, mutect2, varscan2
- OR8G5 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100422202; called by muse, mutect2, varscan2
- PPP1R18 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99223537; called by muse, mutect2, varscan2
- RABAC1 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99706004; called by muse, mutect2, varscan2
- RAI1 | c.4051G>T p.A1351S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs778842491, COSV99883248; called by mutect2, varscan2
- SDS | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV99980904; called by muse, mutect2, varscan2
- SIGLEC5 | c.840C>A p.S280R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99707058; called by muse, mutect2
- SLC26A2 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99639974; called by muse, mutect2, varscan2
- SLC5A8 | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV101610510; called by muse, mutect2
- SLC8B1 | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.056); catalogued as COSV99176641; called by muse, mutect2, varscan2
- SLIT1 | c.2323C>A p.L775M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99820511; called by muse, mutect2, varscan2
- SOS2 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1447501425; called by muse, mutect2
- SPEF2 | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV61553708; called by muse, varscan2
- SRI | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.203); catalogued as COSV99719706; called by mutect2, varscan2
- TBK1 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.978); catalogued as COSV100537980; called by muse, mutect2
- TBX19 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as COSV100892325; called by muse, mutect2
- TMC6 | c.2043C>A p.C681* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs560735308, COSV100129884; called by muse, mutect2, varscan2
- TMEM204 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV54153615, COSV99559673; called by muse, mutect2
- TRANK1 | c.5762C>A p.A1921D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100081311; called by muse, mutect2, varscan2
- TUBE1 | c.1199C>A p.A400E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100036892; called by muse, varscan2
- VSIG4 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.903); catalogued as COSV101038039; called by muse, mutect2
- WDR72 | c.920A>T p.H307L | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV64742967; called by muse, mutect2, varscan2
- WWC3 | c.2780G>T p.S927I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101080981, COSV66502647; called by mutect2, varscan2
- ZBTB32 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs767265045, COSV99385841; called by mutect2, varscan2
- ZDBF2 | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100984314; called by muse, mutect2
- ZMYM4 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV100109416; called by muse, mutect2, varscan2
- DDX4 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- ESR2 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FBN3 | c.7661_7663delinsAA p.P2554Qfs*144 | Frame Shift Del (DEL) | VAF 24/33 reads (73%) | called by pindel, varscan2*
- GPR19 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- IL4I1 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- KIF24 | c.2522C>A p.A841D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, varscan2
- LHFPL3 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2
- LRRC1 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NACC2 | c.343C>A p.R115S | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- PNPT1 | c.2023C>A p.Q675K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.309); called by muse, varscan2
- RIN2 | c.859G>T p.A287S (on ENST00000255006 / NM_001242581.1; = p.A238S on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SEZ6 | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- USP28 | c.2354C>A p.A785D | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- VIL1 | c.1227G>T p.E409D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.211); called by mutect2, varscan2
- ZC3H7B | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.076); called by muse, varscan2
- ZRANB3 | c.2398C>A p.Q800K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); called by muse, mutect2
- CEP89 | c.1431C>T p.H477= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs376354209; called by muse, mutect2, varscan2
- COL2A1 | c.1314C>A p.G438= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100475336; called by mutect2, varscan2
- CRYGB | c.348C>A p.R116= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99649888; called by mutect2, varscan2
- DCST2 | c.834T>G p.R278= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV99791602; called by muse, mutect2, varscan2
- DIDO1 | c.4221C>A p.R1407= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99824564; called by mutect2, varscan2
- FZD6 | c.504T>C p.S168= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs775449278, COSV100708284; called by muse, mutect2, varscan2
- GRM4 | c.2088C>T p.P696= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs1425782036, COSV65211916; called by muse, mutect2, varscan2
- H2AC20 | c.177G>A p.L59= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV100479667, COSV58611473; called by muse, mutect2, varscan2
- HTRA2 | c.309G>T p.S103= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- IPO4 | c.3087C>A p.L1029= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100268851; called by muse, varscan2
- KCNH3 | c.1425G>A p.T475= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs765673802, COSV99234666; called by muse, varscan2
- PCLO | c.2358A>G p.Q786= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs1345074198, COSV100427049; called by muse, mutect2, varscan2
- PLCH1 | c.2655C>G p.L885= (on ENST00000340059 / NM_001130960.2; = p.L877= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs143064400; called by muse, mutect2, varscan2
- PLPP6 | c.483C>T p.A161= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1171149265, COSV99794791, COSV99795104; called by muse, mutect2, varscan2
- SCARF1 | c.1536G>A p.P512= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as rs200330951, COSV99556813; called by muse, mutect2, varscan2
- SHROOM2 | c.4356G>T p.R1452= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV101098108; called by muse, varscan2
- SLC16A11 | c.723C>A p.R241= (on ENST00000308009; = p.R217= on NM_153357.3) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100338548; called by mutect2, varscan2
- TMEM62 | c.1314G>T p.V438= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53040068; called by mutect2, varscan2
- TNC | c.3714C>T p.V1238= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV100404875; called by muse, mutect2, varscan2
- VTN | c.969C>A p.G323= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99411976; called by muse, varscan2
- VWF | c.1365T>G p.L455= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV99777825; called by muse, mutect2, varscan2
- ZFP36 | c.807G>T p.G269= (on ENST00000594442; = p.G263= on NM_003407.5) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99953649; called by muse, mutect2
- ZMYM1 | c.1200G>A p.T400= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs778430724, COSV100720884; called by muse, mutect2, varscan2
- ZNF318 | c.1998T>C p.A666= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV100545920; called by muse, mutect2, varscan2
- ADAMTSL2 | c.-2G>T | 5'UTR (SNP) | VAF 42/69 reads (61%) | catalogued as COSV100618873; called by muse, mutect2, varscan2
- CSH2 | c.456+11C>T | Intron (SNP) | VAF 34/77 reads (44%) | catalogued as COSV61079989; called by muse, mutect2, varscan2
- SSPOP | n.8875G>A | RNA (SNP) | VAF 21/32 reads (66%) | catalogued as COSV100946960; called by muse, mutect2, varscan2
